Somatic mutation profile of tumor specimen TCGA-BQ-5893-01A (aliquot TCGA-BQ-5893-01A-11D-1589-08) from TCGA case TCGA-BQ-5893, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 61.1 years (22,320 days).
Specimen TCGA-BQ-5893-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 499e9f29-d693-4dec-8529-d4dca9c829aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5893-11A (Solid Tissue Normal), aliquot TCGA-BQ-5893-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12babfcb-a9fe-4923-a424-349f189f3f20

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 16, In Frame Del 1, RNA 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64606264; called by muse, mutect2, varscan2
- ANKRD11 | c.3033G>C p.K1011N | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV56367145, COSV56371447; called by muse, mutect2, varscan2
- CIITA | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); catalogued as COSV100161517, COSV60861942; called by muse, mutect2, varscan2
- CNFN | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV55772309; called by muse, mutect2, varscan2
- CSMD3 | c.10515C>A p.Y3505* (on ENST00000297405 / NM_001363185.1; = p.Y3336* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as COSV52311916, COSV99834006, COSV99846545; called by muse, varscan2
- DMPK | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV52174959, COSV52182176; called by muse, mutect2, varscan2
- EBF2 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs200594181; called by muse, mutect2, varscan2
- EIF1AX | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100792184, COSV63309475; called by muse, mutect2, varscan2
- JAK1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61096343; called by muse, mutect2, varscan2
- KIR3DL3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767458176, COSV99400127; called by muse, mutect2, varscan2
- KMT2C | c.13273G>T p.D4425Y | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51487965, COSV51502540; called by muse, mutect2, varscan2
- LARS1 | c.1183G>A p.D395N (on ENST00000394434 / NM_020117.11; = p.D368N on NM_016460.3) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762386770, COSV50978768; called by muse, mutect2, varscan2
- MYO15A | c.10533C>A p.N3511K | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV52765602; called by muse, mutect2, varscan2
- MYOM2 | c.2263A>G p.K755E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1251611794, COSV50769372; called by muse, mutect2, varscan2
- OR13A1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs200530280, COSV65572673; called by muse, mutect2, varscan2
- OR13G1 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1218011154, COSV62945278; called by muse, mutect2, varscan2
- PCDHB2 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV99166325; called by muse, varscan2
- PICALM | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV100707890, COSV62674088; called by muse, mutect2, varscan2
- PKD1L1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs758722669, COSV56977479; called by muse, mutect2, varscan2
- PRKCG | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54732657; called by muse, mutect2, varscan2
- RHPN2 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54284516; called by muse, mutect2, varscan2
- SHISA2 | c.831G>C p.Q277H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100096383, COSV60111928; called by muse, mutect2, varscan2
- SLC9C2 | c.1734C>A p.F578L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV62945563; called by muse, mutect2, varscan2
- SPATA13 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV66069105, COSV66071714; called by muse, mutect2, varscan2
- SPATA31D1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV61194835, COSV61201105; called by muse, mutect2, varscan2
- SVEP1 | c.10295A>G p.Y3432C | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV52843877; called by muse, mutect2, varscan2
- TPK1 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63647928; called by muse, mutect2, varscan2
- TTC17 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.066); catalogued as COSV50019674; called by muse, mutect2, varscan2
- BCORL1 | c.4517_4520dup p.L1508Afs*34 | Frame Shift Ins (INS) | VAF 22/34 reads (65%) | called by mutect2, pindel, varscan2
- CERT1 | c.1094_1099del p.N365_G366del (on ENST00000405807 / NM_001130105.1; = p.N237_G238del on NM_005713.3) | In Frame Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- TXNRD1 | c.1542+4_1542+7del p.X514_splice (on ENST00000525566 / NM_001093771.3; = p.X416_splice on NM_003330.4) | Splice Site (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- ANXA3 | c.963A>T p.G321= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV53717323; called by muse, mutect2, varscan2
- DENND3 | c.2379C>T p.F793= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs374490803; called by muse, mutect2, varscan2
- DENND4A | c.3780G>A p.V1260= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV71266975; called by muse, mutect2, varscan2
- FAM110B | c.945C>T p.S315= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100826202, COSV64068000; called by muse, mutect2, varscan2
- FAM83H | c.2514C>G p.A838= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV62030095; called by muse, mutect2, varscan2
- GARRE1 | c.2082G>A p.L694= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV55103950; called by muse, mutect2, varscan2
- GPR34 | c.549T>A p.L183= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV59375141; called by muse, mutect2, varscan2
- GRPEL2 | c.582C>T p.T194= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs779260160, COSV61388201; called by muse, mutect2, varscan2
- IGFLR1 | c.582C>G p.A194= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV53076566; called by muse, mutect2, varscan2
- MYBL1 | c.2151A>T p.T717= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV72919216; called by muse, mutect2, varscan2
- OR1B1 | c.315C>T p.F105= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV59172366; called by muse, mutect2, varscan2
- PRRC2C | c.1435A>C p.R479= (on ENST00000367742; = p.R477= on NM_015172.4) | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs14798, COSV100145850; called by muse, varscan2
- RELCH | c.813C>T p.N271= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV56892022; called by muse, mutect2, varscan2
- SAMD5 | c.36G>A p.A12= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs745370093, COSV66586614; called by muse, mutect2, varscan2
- SIN3A | c.1770G>A p.S590= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs373830836; called by muse, mutect2, varscan2
- SMARCA2 | c.3351C>T p.S1117= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV61812434; called by muse, mutect2, varscan2
- ZNF767P | n.317C>A | RNA (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
